ALCHEMIST case ALCH-B2VL — Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial (ALCHEMIST-ALCH)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026).
https://portal.gdc.cancer.gov/cases/7e8c3687-64ca-4a39-b33c-94ea4303910b

Demographics
Sex at birth: male.

Diagnoses (1)
1. Pleomorphic carcinoma: Age at diagnosis: 65.8 years (24,051 days).

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ALCH-B2VL-NB1-A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Fresh.
- Sample ALCH-B2VL-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ALCH-B2VL-TTP1-A-1-0-S2: Section location: Top; Percent tumor cells: 29; Percent tumor nuclei: 46; Percent normal cells: 23; Percent necrosis: 2; Percent stromal cells: 46; Percent lymphocyte infiltration: 36; Percent monocyte infiltration: 3; Percent neutrophil infiltration: 0.
